CPTAC case C3L-07036 — Pancreas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/f18c9bec-1c23-45f1-a6df-0113f1d851c1

Demographics
Sex at birth: male; Race: white; Year of birth: 1940.

Other clinical attributes
- Weight: 80.2 kg; Height: 182 cm; BMI: 24.21.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1965; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (1 sample)
- Sample C3L-07036-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 240 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
